Somatic mutation profile of tumor specimen TCGA-DB-A4X9-01A (aliquot TCGA-DB-A4X9-01A-11D-A26M-08) from TCGA case TCGA-DB-A4X9, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Temporal lobe; Tumor grade: G2; Age at diagnosis: 33.2 years (12,131 days).
Specimen TCGA-DB-A4X9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4de68379-69c0-48a6-b40b-adfa51da27b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4X9-10A (Blood Derived Normal), aliquot TCGA-DB-A4X9-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba918416-92d4-44f6-aeee-cf0c1636c1a9

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Ins 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATRX | c.4555G>T p.E1519* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100969773; called by mutect2, varscan2
- CES3 | c.1521-1G>A p.X507_splice | Splice Site (SNP) | VAF 28/72 reads (39%) | catalogued as COSV57594730; called by muse, mutect2, varscan2
- COL1A2 | c.3326A>G p.D1109G | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV51963293; called by muse, mutect2, varscan2
- CYP4A11 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs765836836, COSV60223334; called by muse, mutect2, varscan2
- DCLRE1B | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200186734, COSV65813393; called by muse, mutect2, varscan2
- ERBB4 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.709); catalogued as COSV53565255; called by muse, mutect2, varscan2
- FAM9B | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59120094; called by muse, mutect2, varscan2
- FARS2 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as COSV51172348; called by muse, mutect2, varscan2
- FEZF2 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV51864071; called by muse, mutect2, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 22/50 reads (44%) | catalogued as rs1022402829; called by mutect2, varscan2
- REXO1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV50085403, COSV99402443; called by muse, mutect2, varscan2
- RHPN2 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV54280832; called by muse, mutect2, varscan2
- SASH3 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760525860, COSV63555662; called by muse, mutect2, varscan2
- SMAD3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1429991069, COSV59287781; called by muse, mutect2, varscan2
- SYNJ2 | c.4058G>A p.S1353N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs1255067061, COSV62898433; called by muse, mutect2, varscan2
- TLK1 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV62631927; called by muse, varscan2
- TOR1AIP2 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as rs1188835981, COSV62626832; called by muse, mutect2, varscan2
- VPS13C | c.3243T>G p.I1081M (on ENST00000644861 / NM_020821.3; = p.I1038M on NM_017684.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV51365615; called by muse, mutect2, varscan2
- KHDC4 | c.1633del p.T545Qfs*11 | Frame Shift Del (DEL) | VAF 115/315 reads (37%) | called by mutect2, pindel, varscan2
- NETO1 | c.414dup p.A139Cfs*2 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- RBM27 | c.327del p.E110Nfs*67 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- FGL2 | c.874C>T p.L292= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV50384176; called by muse, mutect2
- MORC4 | c.2172A>T p.A724= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV55245309; called by muse, mutect2, varscan2
- OR2T2 | c.222C>T p.Y74= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV61618687; called by muse, mutect2, varscan2
- SLC9A3 | c.441C>T p.A147= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs372546363; called by muse, mutect2
